Somatic mutation profile of tumor specimen TARGET-10-PATRHL-09A (aliquot TARGET-10-PATRHL-09A-01D) from TARGET case TARGET-10-PATRHL, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.3 years (2,299 days).
Specimen TARGET-10-PATRHL-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b7b2d521-e023-4230-b7d3-f5c6e22defd6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PATRHL-10A (Blood Derived Normal), aliquot TARGET-10-PATRHL-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/96583278-6958-4a73-81f0-cbdc910744fd

The open-access MAF lists 28 somatic variants for this specimen: 18 protein-altering or splice-affecting, 6 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 6, 3'UTR 2, In Frame Ins 2, Intron 2, Nonsense Mutation 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALPI | c.334G>A p.A112T | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs371086927; called by muse, mutect2, varscan2
- BCL11B | c.1415G>A p.R472H (on ENST00000357195 / NM_001282237.2; = p.R401H on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1231938148, COSV61734054; called by muse, mutect2
- CCDC27 | c.373C>T p.R125* | Nonsense Mutation (SNP) | VAF 23/47 reads (49%) | catalogued as rs760910706, COSV53898240; called by muse, mutect2, varscan2
- CUL3 | c.1678A>G p.N560D | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.627); catalogued as COSV52362184; called by muse, mutect2, varscan2
- GALNT8 | c.154C>T p.R52C | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.248); catalogued as rs201036640; called by muse, mutect2
- HS3ST5 | c.151C>T p.R51C | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.116); catalogued as rs144333146; called by muse, mutect2, varscan2
- LDLRAD2 | c.793G>A p.A265T | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs187938808, COSV60827683; called by muse, mutect2, varscan2
- MYO1G | c.1306G>C p.E436Q | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs545754641, COSV51853470; called by muse, mutect2
- NCOR2 | c.1654G>A p.D552N | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as rs757008502, COSV62294507; called by muse, mutect2
- NOTCH1 | c.5039T>C p.I1680T | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); catalogued as COSV53025693, COSV53032125, COSV53096766; called by muse, mutect2, varscan2
- RYR2 | c.3807G>T p.E1269D | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.014); catalogued as COSV63668848; called by muse, mutect2
- SPTBN2 | c.5098C>T p.R1700C | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.86); catalogued as rs1185093392, COSV59448363; called by muse, mutect2, varscan2
- UHRF1 | c.221G>T p.R74L (on ENST00000612630 / NM_001290050.1; = p.R87L on NM_013282.4) | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53573468; called by muse, mutect2, varscan2
- WFDC9 | c.237C>T p.N79= | Splice Region (SNP) | VAF 13/30 reads (43%) | catalogued as rs557112902, COSV58096107; called by muse, mutect2, varscan2
- ZNF469 | c.1805G>A p.G602D | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.57); catalogued as COSV71258322; called by muse, mutect2, varscan2
- ZNF541 | c.2327C>G p.A776G | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54543179; called by muse, mutect2, varscan2
- IL7R | c.767_768insCCTAGAGTT p.L255_L256insFLE | In Frame Ins (INS) | VAF 13/40 reads (33%) | called by mutect2, pindel, varscan2
- POLE | c.2408_2409insTCCCAAATCTTGCTCTTTGTACTCCCGTCCTTC p.S803_L804insPKSCSLYSRPS | In Frame Ins (INS) | VAF 10/26 reads (38%) | called by mutect2, pindel
- APOL1 | c.489T>C p.D163= | Silent (SNP) | VAF 20/46 reads (43%) | catalogued as rs1255147713; called by muse, mutect2, varscan2
- CSMD2 | c.1755G>A p.P585= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as rs200697809; called by muse, mutect2, varscan2
- GRIN3B | c.1386G>A p.A462= | Silent (SNP) | VAF 12/24 reads (50%) | catalogued as rs1175293732; called by muse, mutect2, varscan2
- PTPN7 | c.1008G>A p.T336= (on ENST00000495688; = p.T375= on NM_002832.4 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 21/49 reads (43%) | catalogued as rs374490952; called by muse, mutect2, varscan2
- TDRD6 | c.534C>G p.R178= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as COSV100288462; called by muse, mutect2
- TSHZ3 | c.2052C>T p.L684= | Silent (SNP) | VAF 9/21 reads (43%) | catalogued as rs765207999; called by muse, mutect2, varscan2
- EPHB4 | c.809-33G>C | Intron (SNP) | VAF 4/17 reads (24%) | called by muse, mutect2
- OR2C3 | c.*4628_*4630del | 3'UTR (DEL) | VAF 14/38 reads (37%) | catalogued as rs1446066113; called by pindel, varscan2
- PHYHIPL | c.106+539G>A | Intron (SNP) | VAF 11/39 reads (28%) | catalogued as COSV65850311; called by muse, mutect2, varscan2
- RETNLB | c.*137C>A | 3'UTR (SNP) | VAF 6/13 reads (46%) | called by muse, mutect2, varscan2
